Somatic mutation profile of tumor specimen C3L-01307-01 (aliquot CPT0064290007) from CPTAC case C3L-01307, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 74.6 years (27,242 days).
Specimen C3L-01307-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 709c9366-2677-4892-b128-46792582c97a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01307-31 (Blood Derived Normal), aliquot CPT0065410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10608c0a-a531-40c8-8e7a-b948a90f05f3

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Intron 4, Nonsense Mutation 4, 5'UTR 3, In Frame Del 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLD | c.104dup p.Y35* | Nonsense Mutation (INS) | VAF 24/108 reads (22%) | catalogued as rs753234219, CI962265; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 27/105 reads (26%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs587782316, CM1411653, COSV64288862, COSV64310637, COSV64311330; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | hotspot (GDC flag); catalogued as rs587782607, CM116000, COSV100909697, COSV64292178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 222/477 reads (47%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.5870C>T p.A1957V | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as rs922813408, COSV56354726; called by muse, mutect2, varscan2
- AXL | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV56571030; called by muse, mutect2, varscan2
- CCDC85B | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.434); catalogued as COSV57029065; called by muse, mutect2, varscan2
- CRACR2A | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs759439857; called by muse, mutect2, varscan2
- CYP4F2 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751427624, COSV99686261; called by muse, mutect2, varscan2
- FANCA | c.1682C>T p.T561M | Missense Mutation (SNP) | VAF 100/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148154682, CM137882, COSV101225074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR20 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs1297722431; called by muse, mutect2, varscan2
- HTR4 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100087525; called by muse, mutect2
- HTR7 | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV53289846; called by muse, mutect2, varscan2
- KIAA1210 | c.4244C>G p.S1415C | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV68177738; called by muse, mutect2
- LRTM2 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs770648822; called by muse, mutect2, varscan2
- NRXN2 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs780057301; called by muse, mutect2
- PCDHA5 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as rs1341974527; called by muse, mutect2
- PROKR2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 109/477 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs143647776, COSV99449714; called by muse, mutect2, varscan2
- SEC14L6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as rs1444848482; called by muse, mutect2, varscan2
- ZNF362 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV65031794; called by muse, varscan2
- ZNF709 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs1258055711, COSV67194456; called by muse, mutect2, varscan2
- ACTR3B | c.1161+1G>A p.X387_splice | Splice Site (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- AGRN | c.5483A>T p.N1828I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CHD4 | c.3183+1G>A p.X1061_splice (on ENST00000357008 / NM_001363606.2; = p.X1074_splice on NM_001273.5) | Splice Site (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- CIP2A | c.1722_1724del p.H575del | In Frame Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- CRCP | c.21T>A p.N7K | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CWC15 | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- DNAJC2 | c.1264A>C p.I422L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- DSEL | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EP300 | c.7107G>C p.Q2369H | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); called by muse, mutect2
- FUT2 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 134/501 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- LRRK2 | c.1057T>G p.C353G | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- POLR2B | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PPP1R12A | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF8 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 34/864 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF527 | c.1621C>G p.L541V | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ADCY8 | c.222C>T p.G74= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1321526692, COSV99655307; called by muse, mutect2, varscan2
- AHNAK2 | c.10773A>G p.E3591= | Silent (SNP) | VAF 61/318 reads (19%) | catalogued as rs751142162; called by muse, mutect2, varscan2
- CEACAM20 | c.69A>C p.V23= | Silent (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- COL9A2 | c.1344C>T p.G448= | Silent (SNP) | VAF 79/303 reads (26%) | called by muse, mutect2, varscan2
- DSCAM | c.5622T>A p.S1874= | Silent (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- FAM83B | c.1080T>C p.P360= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- GRM1 | c.2583C>T p.G861= | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as rs148042148; called by muse, mutect2, varscan2
- PLEKHG5 | c.2781C>T p.G927= (on ENST00000400915 / NM_001042663.3; = p.G890= on NM_020631.6) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1271066564; called by muse, mutect2, varscan2
- ARHGAP22 | c.-25G>A | 5'UTR (SNP) | VAF 42/178 reads (24%) | catalogued as rs1430462353; called by muse, mutect2, varscan2
- BBS9 | c.2521+17T>C | Intron (SNP) | VAF 72/401 reads (18%) | catalogued as rs745474202; called by muse, mutect2, varscan2
- CDKL1 | c.171+18140T>G | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- EIF1 | c.196-34G>A | Intron (SNP) | VAF 51/168 reads (30%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.-18G>C | 5'UTR (SNP) | VAF 14/442 reads (3%) | called by muse, mutect2
- LEPR | c.2674-5947del | Intron (DEL) | VAF 31/136 reads (23%) | called by mutect2, pindel, varscan2
- PYM1 | c.-25A>G | 5'UTR (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
